Somatic mutation profile of tumor specimen TCGA-J9-A8CN-01A (aliquot TCGA-J9-A8CN-01A-11D-A34U-08) from TCGA case TCGA-J9-A8CN, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 53.8 years (19,662 days).
Specimen TCGA-J9-A8CN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b17e3efe-6456-4205-9ce4-d3aa5814747b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-J9-A8CN-10A (Blood Derived Normal), aliquot TCGA-J9-A8CN-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b1a53de-cb50-464f-91fb-2ef4eb1aca80

The open-access MAF lists 19 somatic variants for this specimen: 14 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 14, Silent 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C19orf44 | c.190C>A p.L64M | Missense Mutation (SNP) | VAF 66/167 reads (40%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.773); catalogued as COSV99522156; called by muse, mutect2, varscan2
- DDR1 | c.764A>G p.Y255C | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs759637254, COSV100241433; called by muse, mutect2
- DENND1A | c.1622G>A p.G541D | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV101011935; called by muse, mutect2
- KLK15 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as rs571715638, COSV56825833, COSV56826507; called by muse, mutect2, varscan2
- LHX9 | c.119G>T p.R40I | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100435818; called by muse, mutect2
- MACF1 | c.18773T>C p.V6258A (on ENST00000372915; = p.V4303A on NM_012090.5) | Missense Mutation (SNP) | VAF 7/78 reads (9%) | catalogued as COSV99243667; called by muse, mutect2
- MBTPS1 | c.1089T>G p.F363L | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.593); catalogued as COSV100597544; called by muse, mutect2, varscan2
- MYH8 | c.541G>A p.G181R | Missense Mutation (SNP) | VAF 54/118 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs181130030, COSV67961216; called by muse, mutect2, varscan2
- NDUFB9 | c.241A>G p.I81V | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as COSV99412772; called by muse, mutect2
- PFKL | c.1991G>A p.G664D | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100297157; called by muse, varscan2
- PKD1 | c.6619C>T p.P2207S | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV99237952; called by muse, mutect2
- RALGDS | c.1684G>A p.G562S | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64428542; called by muse, mutect2, varscan2
- TNP1 | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.987); catalogued as rs561435538, COSV52696595; called by muse, mutect2, varscan2
- XRN1 | c.395G>A p.C132Y | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99377812; called by muse, mutect2, varscan2
- LCE1C | c.321C>T p.G107= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs551622346, COSV64218139, COSV64218259; called by mutect2, varscan2
- LRRK1 | c.4242G>A p.R1414= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as rs547652242, COSV99439335; called by muse, mutect2, varscan2
- MYH7 | c.4824C>A p.R1608= | Silent (SNP) | VAF 11/112 reads (10%) | catalogued as COSV100806012; called by muse, mutect2
- SIGLEC5 | c.1497C>T p.P499= | Silent (SNP) | VAF 34/74 reads (46%) | catalogued as rs141897891; called by muse, mutect2, varscan2
- ZNF91 | c.921A>T p.S307= | Silent (SNP) | VAF 53/136 reads (39%) | catalogued as COSV100322592; called by muse, mutect2, varscan2
